Gene-level copy-number profile of tumor specimen TCGA-D1-A0ZZ-01A from TCGA case TCGA-D1-A0ZZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 80.5 years (29,420 days).
Specimen TCGA-D1-A0ZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.38e02a30-4bca-4031-b90f-9df7697093f6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A0ZZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/06dd96b2-b4e5-4602-b857-3ee1d271a2d4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,057; copy number 2: 13,694; copy number 3: 14,519; copy number 4: 23,952; copy number 5: 2,859; copy number 6: 2,915; copy number 7: 368; copy number 8: 30; copy number 9: 138; copy number 11: 76; copy number 13: 4; copy number 15: 5; copy number 16: 1; copy number 17: 108; copy number 18: 41; copy number 23: 18; copy number 34: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A0ZZ-01A-11D-A10L-01): tumor purity 0.86, ploidy 3.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,858,127–9,442,380, 4 genes: PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 415 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,691,648–41,242,154, 15 genes, copy number 9 (within-gene range 4–9): NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1, AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1, SCMH1, RPL23AP17.
- chr5:59,528,861–59,529,251, 1 gene, copy number 15: NDUFB4P2.
- chr7:67,627,831–71,713,600, 27 genes, copy number 11–15 (within-gene range 2–15): MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2, AC073873.1, GALNT17, MIR3914-1, MIR3914-2.
- chr8:69,667,046–74,823,313, 99 genes, copy number 9–23 (within-gene range 6–23) (broad region; genes not listed).
- chr8:78,148,101–78,153,913, 1 gene, copy number 16: AC084706.1.
- chr8:79,747,351–84,142,463, 77 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:122,091,480–129,683,770, 132 genes, copy number 17–34 (within-gene range 7–34) (broad region; genes not listed).
- chr15:27,418,796–28,322,179, 10 genes, copy number 9–13 (within-gene range 6–13): AC104002.1, AC104002.2, AC104002.3, AC021979.1, AC021979.3, AC021979.2, OCA2, AC090696.1, RPL5P32, HERC2.
- chr22:20,241,415–20,283,246, 1 gene, copy number 11 (within-gene range 1–11): RTN4R.
- chr22:20,299,760–21,122,285, 52 genes, copy number 11: AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4, BCRP2.

Autosomal genes at a single copy (total copy number 1): 1,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
